Somatic mutation profile of tumor specimen C3N-00580-03 (aliquot CPT0069700006) from CPTAC case C3N-00580, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 56.8 years (20,730 days).
Specimen C3N-00580-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1062fb1d-a5c7-4308-a595-5ec74f627784.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00580-71 (Blood Derived Normal), aliquot CPT0069800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7d193f0-4a9d-4dc1-af31-553580c7b2b4

The open-access MAF lists 1,189 somatic variants for this specimen: 829 protein-altering or splice-affecting, 224 silent, 136 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 713, Silent 224, Intron 58, Nonsense Mutation 46, RNA 34, Splice Site 27, Frame Shift Del 23, 3'UTR 15, 5'Flank 14, 5'UTR 11, Splice Region 9, Frame Shift Ins 6.

Variants (750 of 1,189; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 246/379 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 212/584 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 121/207 reads (58%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV59390100; called by muse, mutect2, varscan2
- ABCA10 | c.4225C>T p.R1409C | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs771145174, COSV52226582; called by muse, mutect2, varscan2
- ACSM2A | c.18A>C p.K6N | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.466); catalogued as rs752798612; called by muse, varscan2
- ADARB2 | c.1481G>T p.R494I | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67229410; called by muse, mutect2, varscan2
- ADCY2 | c.2776-1G>T p.X926_splice | Splice Site (SNP) | VAF 63/578 reads (11%) | catalogued as COSV57858955; called by muse, mutect2, varscan2
- ADD2 | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.408); catalogued as COSV52459669; called by muse, mutect2, varscan2
- AGFG2 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.972); catalogued as rs1486073318; called by muse, mutect2, varscan2
- AMDHD1 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766753928; called by muse, mutect2, varscan2
- ANHX | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 72/295 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.059); catalogued as rs752519244; called by muse, mutect2, varscan2
- ANK2 | c.8509G>T p.A2837S | Missense Mutation (SNP) | VAF 159/474 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.033); catalogued as COSV52148025; called by muse, mutect2, varscan2
- APBB3 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs574632516; called by muse, mutect2, varscan2
- APOB | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 171/408 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51941992; called by muse, mutect2, varscan2
- ARHGAP4 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 81/472 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63134846; called by muse, mutect2, varscan2
- ASCL2 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs976139581; called by muse, mutect2, varscan2
- ASXL3 | c.3289A>T p.R1097* | Nonsense Mutation (SNP) | VAF 36/144 reads (25%) | catalogued as COSV52465203; called by muse, mutect2, varscan2
- ASXL3 | c.3290G>T p.R1097I | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99326402; called by muse, mutect2, varscan2
- ATP8A2 | c.3182A>T p.Q1061L | Missense Mutation (SNP) | VAF 82/148 reads (55%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.6); catalogued as rs371456534; called by muse, mutect2, varscan2
- ATP8B4 | c.3028-1G>T p.X1010_splice | Splice Site (SNP) | VAF 33/81 reads (41%) | catalogued as COSV52712118; called by muse, mutect2, varscan2
- BCHE | c.1721G>T p.G574V | Missense Mutation (SNP) | VAF 40/330 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.845); catalogued as COSV52253812; called by muse, mutect2, varscan2
- BCL11B | c.1525G>T p.G509C (on ENST00000357195 / NM_001282237.2; = p.G438C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/282 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs948335245; called by muse, mutect2, varscan2
- BCLAF1 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV62140405; called by muse, mutect2, varscan2
- BRDT | c.1225G>T p.G409W | Missense Mutation (SNP) | VAF 42/287 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs772740692; called by muse, mutect2, varscan2
- C2CD6 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs199804981; called by muse, mutect2, varscan2
- C2orf16 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 59/342 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); catalogued as rs1479746703, COSV101284405; called by muse, mutect2, varscan2
- C4orf17 | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV100430794; called by muse, mutect2, varscan2
- CACNA1E | c.4882-1G>T p.X1628_splice | Splice Site (SNP) | VAF 68/158 reads (43%) | catalogued as COSV62400190; called by muse, mutect2, varscan2
- CACNA1G | c.6923C>A p.P2308Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as rs1216824387; called by muse, mutect2
- CACNA2D1 | c.845C>G p.T282S | Missense Mutation (SNP) | VAF 94/463 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100667347; called by muse, mutect2, varscan2
- CARMIL3 | c.2102G>T p.R701L | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.24); catalogued as COSV100549297; called by muse, mutect2, varscan2
- CASQ2 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 165/409 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV54772883; called by muse, mutect2, varscan2
- CCDC127 | c.165G>T p.E55D | Missense Mutation (SNP) | VAF 54/333 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs767709061; called by muse, varscan2
- CCER1 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62646650, COSV62646730; called by muse, mutect2, varscan2
- CDC73 | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 129/565 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV66470933; called by muse, mutect2, varscan2
- CDK9 | c.916A>C p.S306R | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763822642; called by muse, mutect2, varscan2
- CDYL2 | c.369G>T p.K123N | Missense Mutation (SNP) | VAF 88/185 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.083); catalogued as rs1013394913; called by muse, mutect2, varscan2
- CEACAM18 | c.287G>T p.R96I | Missense Mutation (SNP) | VAF 182/363 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as COSV67283781; called by muse, mutect2, varscan2
- CFAP74 | c.4443C>A p.F1481L | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs768973631, COSV60587959; called by muse, mutect2
- CGB2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 64/100 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100031736; called by mutect2, varscan2
- CHST3 | c.386C>A p.A129E | Missense Mutation (SNP) | VAF 387/577 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs147535559; called by muse, mutect2, varscan2
- COL11A1 | c.2663G>T p.R888L | Missense Mutation (SNP) | VAF 222/558 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV62182312; called by muse, mutect2, varscan2
- COL15A1 | c.3110del p.G1037Vfs*116 | Frame Shift Del (DEL) | VAF 66/236 reads (28%) | catalogued as COSV66644935; called by mutect2, pindel, varscan2
- COL15A1 | c.3307C>A p.P1103T | Missense Mutation (SNP) | VAF 85/158 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775032043; called by muse, mutect2, varscan2
- COL6A3 | c.3700G>A p.V1234M | Missense Mutation (SNP) | VAF 69/458 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs747082651, COSV55086007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.1252T>A p.Y418N | Missense Mutation (SNP) | VAF 201/461 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV55100216; called by muse, mutect2, varscan2
- CORO2B | c.1202A>G p.Y401C | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs372267861; called by muse, mutect2, varscan2
- CPA5 | c.779G>C p.R260T | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV100812358; called by muse, varscan2
- CPNE8 | c.1579G>A p.V527I | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs751045719; called by muse, mutect2, varscan2
- CRAT | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1283563840; called by muse, mutect2
- CRB2 | c.1883G>T p.R628L | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV63502614; called by muse, mutect2, varscan2
- CROCC | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 87/421 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs201480427, COSV65009797; called by muse, mutect2, varscan2
- CSMD3 | c.3067G>C p.G1023R (on ENST00000297405 / NM_001363185.1; = p.G919R on NM_052900.3) | Missense Mutation (SNP) | VAF 306/552 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52142360; called by muse, mutect2, varscan2
- CYFIP2 | c.2572G>T p.A858S (on ENST00000616178 / NM_001291722.2; = p.A833S on NM_014376.4) | Missense Mutation (SNP) | VAF 98/301 reads (33%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.956); catalogued as COSV56635928; called by muse, mutect2, varscan2
- CYP4A22 | c.455A>G p.N152S | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs771740217; called by muse, mutect2, varscan2
- CYP4F3 | c.1330C>A p.R444S | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55407391; called by muse, mutect2, varscan2
- DAGLA | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as COSV57198008, COSV99078705; called by muse, mutect2, varscan2
- DGKI | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs754340378; called by muse, mutect2, varscan2
- DLGAP1 | c.2594C>T p.P865L | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59819069; called by muse, mutect2, varscan2
- DNAH17 | c.5770C>G p.R1924G | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67752677; called by muse, mutect2, varscan2
- DNAJA1 | c.1187C>A p.T396N | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV58311626; called by muse, mutect2, varscan2
- DNAJC5B | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as rs1217304685, COSV52539978; called by muse, mutect2
- DRGX | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs200413142; called by muse, mutect2, varscan2
- EDIL3 | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs368032066; called by muse, mutect2, varscan2
- EHD3 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 85/337 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs144717418; called by muse, mutect2, varscan2
- EIF4G3 | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV51692284; called by muse, mutect2, varscan2
- ELFN2 | c.2404G>C p.E802Q | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68744386; called by muse, mutect2, varscan2
- EPHA5 | c.225G>T p.W75C | Missense Mutation (SNP) | VAF 142/417 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99896708; called by muse, mutect2, varscan2
- EPHA7 | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV65170285; called by muse, mutect2, varscan2
- ERP27 | c.47C>A p.T16K | Missense Mutation (SNP) | VAF 112/227 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs372235750; called by muse, mutect2, varscan2
- EYA4 | c.1058C>A p.S353Y (on ENST00000531901 / NM_001301013.1; = p.S347Y on NM_004100.5) | Missense Mutation (SNP) | VAF 196/446 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.309); catalogued as rs774111274; called by mutect2, varscan2
- FAM135B | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 133/262 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as COSV52713627; called by muse, mutect2, varscan2
- FAM228B | c.69G>T p.W23C | Missense Mutation (SNP) | VAF 92/171 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as rs1478993153; called by muse, mutect2, varscan2
- FAM47C | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.939); catalogued as COSV63723864; called by muse, mutect2, varscan2
- FAM71B | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as COSV57227727; called by muse, varscan2
- FAT2 | c.2561G>T p.R854M | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV99942087; called by muse, mutect2, varscan2
- FBXO8 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 238/427 reads (56%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1365701819, COSV67031512; called by muse, mutect2, varscan2
- FFAR3 | c.545T>A p.L182Q | Missense Mutation (SNP) | VAF 136/1134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59909515; called by muse, mutect2, varscan2
- FGF8 | c.443C>T p.T148M (on ENST00000344255 / NM_033164.4; = p.T130M on NM_006119.6) | Missense Mutation (SNP) | VAF 268/454 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs150575389; called by muse, mutect2, varscan2
- FLNC | c.8104G>T p.G2702W | Missense Mutation (SNP) | VAF 135/456 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99972453; called by muse, mutect2, varscan2
- FOXC1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as CD121393; called by muse, mutect2
- FSIP2 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0.04); catalogued as rs1263959282; called by muse, mutect2, varscan2
- FUBP1 | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1415640741; called by muse, mutect2, varscan2
- GALNT17 | c.857A>G p.Q286R | Missense Mutation (SNP) | VAF 66/653 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.593); catalogued as rs772568078, COSV61147300; called by muse, mutect2, varscan2
- GP2 | c.1478G>T p.R493L (on ENST00000381362 / NM_001007240.3; = p.R490L on NM_001502.4) | Missense Mutation (SNP) | VAF 133/286 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV100221692, COSV56893889; called by muse, mutect2, varscan2
- GPR45 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1352620324; called by muse, mutect2, varscan2
- GRIA1 | c.2721A>C p.*907Yext*52 | Nonstop Mutation (SNP) | VAF 30/270 reads (11%) | catalogued as COSV53588898; called by muse, mutect2
- GRM1 | c.959G>T p.W320L | Missense Mutation (SNP) | VAF 72/383 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99264267; called by muse, mutect2, varscan2
- GSG1L | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 88/248 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1338511209; called by muse, mutect2, varscan2
- HCN1 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 22/283 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV100300372, COSV57538426; called by muse, mutect2
- HDAC9 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs1488919137; called by muse, mutect2, varscan2
- HECW1 | c.174C>A p.H58Q | Missense Mutation (SNP) | VAF 145/580 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.138); catalogued as COSV67820621, COSV67827293; called by muse, mutect2, varscan2
- HR | c.2266C>A p.P756T | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.166); catalogued as rs368256327; called by muse, mutect2, varscan2
- HSPG2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 258/602 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs554613529, COSV65930368; called by muse, mutect2, varscan2
- HTR3B | c.1222C>A p.L408I | Missense Mutation (SNP) | VAF 152/475 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV99491983; called by muse, mutect2, varscan2
- IFRD1 | c.230A>T p.Q77L | Missense Mutation (SNP) | VAF 142/561 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV50044320; called by muse, mutect2
- IGHE | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.53); catalogued as rs782578894; called by muse, mutect2, varscan2
- IL12RB1 | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 74/490 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs865858530, COSV59096650; called by muse, mutect2, varscan2
- IL18RAP | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 79/255 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.201); catalogued as COSV51823778; called by muse, mutect2, varscan2
- IL6 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV51733130; called by muse, mutect2, varscan2
- INSL6 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs553705920; called by muse, mutect2
- INTS7 | c.2040C>A p.S680R | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs200095234; called by muse, mutect2
- IRF5 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 33/359 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs368255860; called by muse, mutect2
- ITGAD | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs562348590; called by muse, mutect2, varscan2
- ITK | c.193A>T p.I65F | Missense Mutation (SNP) | VAF 114/512 reads (22%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as rs758696074; called by muse, mutect2, varscan2
- ITLN1 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100406260; called by muse, mutect2
- JKAMP | c.856G>C p.D286H (on ENST00000554271 / NM_001284201.1; = p.D272H on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/462 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.281); catalogued as rs1042491496; called by muse, mutect2, varscan2
- JPH4 | c.1357C>A p.P453T | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs749448462; called by muse, mutect2, varscan2
- KCNK9 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 215/375 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100271210; called by muse, mutect2, varscan2
- KCNT2 | c.3076C>A p.P1026T | Missense Mutation (SNP) | VAF 118/404 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV54106602; called by muse, mutect2, varscan2
- KIAA1549 | c.776G>A p.S259N | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as rs775674578; called by muse, mutect2
- KIT | c.2299G>C p.E767Q | Missense Mutation (SNP) | VAF 195/708 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV99855108; called by muse, mutect2, varscan2
- KLHL1 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 101/176 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV64771083; called by muse, mutect2, varscan2
- KRIT1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100388553; called by muse, mutect2, varscan2
- KRTAP10-2 | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 453/883 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs587678058; called by muse, mutect2, varscan2
- KRTAP4-11 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 62/464 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs750400835, COSV66948581; called by muse, varscan2
- L1CAM | c.125C>G p.P42R | Missense Mutation (SNP) | VAF 165/577 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100648890; called by muse, mutect2, varscan2
- LAMA1 | c.2643C>A p.H881Q | Missense Mutation (SNP) | VAF 138/488 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV67543204; called by muse, mutect2, varscan2
- LAMA2 | c.98C>A p.A33E | Missense Mutation (SNP) | VAF 136/321 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.193); catalogued as rs750280423, COSV70350269; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA2 | c.196T>C p.Y66H | Missense Mutation (SNP) | VAF 85/411 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs933403803; called by muse, mutect2, varscan2
- LMAN1L | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV100547722, COSV59003215; called by muse, mutect2, varscan2
- LOXHD1 | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs920654744, COSV59668264; called by muse, mutect2
- LPA | c.109C>G p.R37G | Missense Mutation (SNP) | VAF 160/388 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs121912503, COSV60296281; called by muse, mutect2, varscan2
- LRFN5 | c.1647G>T p.M549I | Missense Mutation (SNP) | VAF 77/344 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV53244291, COSV53268624; called by muse, mutect2, varscan2
- LRP2 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 311/861 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.834); catalogued as COSV55564948; called by muse, mutect2, varscan2
- MAGEA11 | c.1119G>T p.Q373H | Missense Mutation (SNP) | VAF 161/219 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100290742; called by muse, mutect2, varscan2
- MAGEA12 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 101/536 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as COSV63294518; called by muse, varscan2
- MAP3K2 | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.443); catalogued as rs560246081; called by muse, varscan2
- MDGA1 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV51791357; called by muse, mutect2, varscan2
- MFSD3 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1233479379; called by muse, mutect2, varscan2
- MKI67 | c.4974_4977dup p.T1660Dfs*13 | Frame Shift Ins (INS) | VAF 134/278 reads (48%) | catalogued as COSV64073126; called by pindel, varscan2
- MLYCD | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 62/159 reads (39%) | catalogued as rs866058038; called by muse, mutect2, varscan2
- MRPL40 | c.44C>G p.P15R | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1435410115; called by muse, mutect2, varscan2
- MTUS2 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 102/196 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV101462295; called by muse, mutect2, varscan2
- MUC17 | c.4100C>G p.P1367R | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100074585; called by muse, mutect2, varscan2
- MUC6 | c.3544del p.Q1182Rfs*42 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as rs754744756; called by mutect2, pindel, varscan2
- MXRA5 | c.5803G>T p.G1935C | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54250099; called by muse, mutect2, varscan2
- MYL10 | c.434T>C p.M145T | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1405332444; called by muse, mutect2
- MYL12A | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54182498; called by muse, mutect2, varscan2
- NKX3-2 | c.706C>G p.R236G | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101219926; called by muse, mutect2, varscan2
- NLRP7 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 240/495 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.825); catalogued as COSV60174420; called by muse, mutect2, varscan2
- NRAP | c.4399C>A p.H1467N (on ENST00000359988 / NM_001322945.2; = p.H1432N on NM_006175.4) | Missense Mutation (SNP) | VAF 93/194 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV63490683; called by muse, mutect2, varscan2
- NRAP | c.3807C>T p.D1269= (on ENST00000359988 / NM_001322945.2; = p.D1234= on NM_006175.4) | Splice Region (SNP) | VAF 129/227 reads (57%) | catalogued as rs777328884, COSV63491131; called by muse, mutect2, varscan2
- NRCAM | c.1014C>A p.Y338* (on ENST00000379028 / NM_001371124.1; = p.Y332* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/118 reads (20%) | catalogued as rs1349065543; called by muse, varscan2
- NTRK3 | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 194/535 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs970508396; called by muse, varscan2
- OR10A5 | c.781T>G p.F261V | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV55055216; called by muse, mutect2
- OR13C2 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV73377725; called by muse, varscan2
- OR1L3 | c.508A>T p.T170S | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as COSV59169462; called by muse, mutect2, varscan2
- OR2A12 | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV68822132; called by muse, mutect2, varscan2
- OR2T3 | c.875C>G p.P292R | Missense Mutation (SNP) | VAF 171/710 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100613333, COSV62082804; called by muse, mutect2, varscan2
- OR4A47 | c.716G>T p.S239I | Missense Mutation (SNP) | VAF 140/442 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV71444843; called by muse, mutect2, varscan2
- OR5AC2 | c.136G>T p.G46* | Nonsense Mutation (SNP) | VAF 51/174 reads (29%) | catalogued as COSV100684401; called by muse, mutect2, varscan2
- OR5AC2 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100684402; called by muse, mutect2, varscan2
- OR5F1 | c.413G>T p.R138M | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV99558726; called by muse, mutect2, varscan2
- OR5R1 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 106/262 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56573139; called by muse, mutect2, varscan2
- OR8I2 | c.541A>T p.T181S | Missense Mutation (SNP) | VAF 16/355 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.026); catalogued as COSV56169846, COSV56170893; called by muse, mutect2
- OR9A4 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV101516376; called by muse, mutect2, varscan2
- OSR1 | c.84C>A p.N28K | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV55346835; called by muse, varscan2
- PAPPA | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 48/484 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1025262255, COSV60285567, COSV60291318; called by muse, mutect2, varscan2
- PCDH19 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 24/455 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV55268409; called by muse, mutect2
- PCDHA8 | c.274C>A p.R92S | Missense Mutation (SNP) | VAF 196/764 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs566154248; called by muse, varscan2
- PCDHGB3 | c.2335G>T p.D779Y | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54023528; called by muse, mutect2, varscan2
- PCK1 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 30/493 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs747489666; called by muse, mutect2
- PHACTR4 | c.788del p.P263Lfs*19 (on ENST00000373839 / NM_001350159.2; = p.P273Lfs*19 on NM_023923.4) | Frame Shift Del (DEL) | VAF 20/138 reads (14%) | catalogued as rs34628351; called by mutect2, pindel
- PLA2G7 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147252565; called by muse, mutect2
- PLAC1 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 97/159 reads (61%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); catalogued as COSV63657248; called by muse, mutect2, varscan2
- PLEKHM2 | c.1916G>T p.R639L | Missense Mutation (SNP) | VAF 93/146 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV65395562; called by muse, mutect2, varscan2
- POLR1A | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as rs781449199; called by muse, mutect2, varscan2
- PRAMEF15 | c.1349C>A p.P450H | Missense Mutation (SNP) | VAF 42/646 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1292642476; called by muse, mutect2
- PRKCB | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57780439; called by muse, mutect2
- PRSS21 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 27/370 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766212468, COSV50052149; called by muse, mutect2
- PSD2 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 66/259 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1053389369; called by muse, mutect2, varscan2
- PTGDR | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as rs201265894, COSV60093766; called by muse, mutect2, varscan2
- PTPRH | c.2498G>T p.S833I | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as COSV99671320, COSV99671485; called by muse, mutect2, varscan2
- PTPRT | c.2383del p.Q795Rfs*64 | Frame Shift Del (DEL) | VAF 44/219 reads (20%) | catalogued as COSV62034279; called by pindel, varscan2*
- PTX4 | c.445G>T p.A149S (on ENST00000447419 / NM_001328608.2; = p.A144S on NM_001013658.1) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as rs764104979, COSV53515031; called by muse, mutect2, varscan2
- RAG1 | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 107/451 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as rs764179803, COSV55024766; called by muse, mutect2, varscan2
- RBPJL | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 67/285 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs574727643; called by muse, mutect2, varscan2
- RIMS2 | c.936G>T p.E312D (on ENST00000666250 / NM_001348490.2; = p.E120D on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 174/299 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as COSV51653532; called by muse, mutect2, varscan2
- RPL27 | c.283G>C p.V95L | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV53815207; called by muse, mutect2, varscan2
- S100A7 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs138333032, COSV64193834; called by muse, mutect2, varscan2
- SCN5A | c.2713del p.D905Tfs*27 | Frame Shift Del (DEL) | VAF 42/235 reads (18%) | catalogued as COSV61142954; called by mutect2, pindel, varscan2
- SEC14L4 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs761871379; called by muse, mutect2, varscan2
- SELPLG | c.1114G>T p.G372W | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57312931; called by muse, mutect2, varscan2
- SEMA5B | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV52092960, COSV99530449; called by muse, mutect2, varscan2
- SKIL | c.767A>G p.K256R | Missense Mutation (SNP) | VAF 65/378 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs1273285421; called by muse, mutect2, varscan2
- SLC3A1 | c.1819C>G p.L607V | Missense Mutation (SNP) | VAF 163/605 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV99575907; called by muse, mutect2, varscan2
- SLC6A12 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.704); catalogued as rs373249721, COSV100675235; called by muse, mutect2, varscan2
- SLC7A9 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 221/425 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99195576; called by muse, mutect2, varscan2
- SLITRK2 | c.2044G>T p.G682C | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100157654, COSV59422638, COSV59427826; called by muse, mutect2, varscan2
- SNAPC4 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1221816864, COSV53738608; called by muse, mutect2, varscan2
- SOX30 | c.691G>C p.A231P | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.324); catalogued as rs779659102; called by muse, mutect2, varscan2
- SPATA20 | c.701G>T p.R234L (on ENST00000356488 / NM_001258372.1; = p.R250L on NM_022827.4) | Missense Mutation (SNP) | VAF 71/377 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs138636087; called by muse, mutect2, varscan2
- SPEM1 | c.584G>T p.W195L | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs958702799; called by mutect2, varscan2
- SRD5A2 | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.297); catalogued as CM033029; called by muse, mutect2
- SSX2IP | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as COSV60552791, COSV60553122; called by muse, mutect2, varscan2
- STK11IP | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99822977; called by muse, mutect2, varscan2
- STYXL2 | c.2675C>A p.A892D | Missense Mutation (SNP) | VAF 86/413 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV54804862; called by muse, mutect2, varscan2
- SYNE1 | c.21817G>A p.D7273N (on ENST00000367255 / NM_182961.4; = p.D7202N on NM_033071.3) | Missense Mutation (SNP) | VAF 206/462 reads (45%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.848); catalogued as COSV99578382; called by muse, mutect2, varscan2
- SYT4 | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54899598, COSV99077754; called by muse, mutect2, varscan2
- TAGAP | c.588-1G>T p.X196_splice | Splice Site (SNP) | VAF 45/195 reads (23%) | catalogued as COSV100487538; called by muse, mutect2, varscan2
- TBC1D4 | c.129dup p.S44Vfs*63 | Frame Shift Ins (INS) | VAF 56/154 reads (36%) | catalogued as rs746138867; called by mutect2, pindel, varscan2
- TEX15 | c.1964C>T p.S655L (on ENST00000256246; = p.S1038L on NM_001350162.2) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868330756; called by muse, mutect2, varscan2
- TEX47 | c.77C>A p.P26Q | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV99787413; called by muse, mutect2, varscan2
- TMEM104 | c.1481C>G p.T494S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs989352666, COSV59109091; called by muse, mutect2
- TMEM121 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.282); catalogued as rs782753165; called by muse, mutect2, varscan2
- TMEM132A | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV50004279; called by muse, mutect2, varscan2
- TPTE | c.1330del p.S444Pfs*5 (on ENST00000618007 / NM_199261.4; = p.S426Pfs*5 on NM_199259.4) | Frame Shift Del (DEL) | VAF 14/150 reads (9%) | catalogued as rs1168082171; called by mutect2, pindel
- TRPC7 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100725389, COSV100725616; called by muse, mutect2, varscan2
- TTC4 | c.818G>T p.R273M | Missense Mutation (SNP) | VAF 154/357 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.694); catalogued as COSV64884341; called by muse, mutect2, varscan2
- TTN | c.31269T>G p.S10423R (on ENST00000591111; = p.S9496R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/246 reads (6%) | PolyPhen benign (0); catalogued as COSV60139713; called by muse, mutect2
- TXNDC2 | c.1294G>T p.G432C (on ENST00000306084 / NM_001098529.2; = p.G365C on NM_032243.6) | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100046120, COSV100046307; called by muse, mutect2, varscan2
- TYK2 | c.1311G>C p.E437D | Missense Mutation (SNP) | VAF 77/421 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs761081566, COSV99314766; called by muse, mutect2, varscan2
- UAP1 | c.1120A>G p.N374D | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773676918; called by muse, mutect2, varscan2
- UMOD | c.1739C>A p.P580H | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100207849; called by muse, mutect2, varscan2
- UMOD | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 44/416 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs376957420; called by muse, mutect2, varscan2
- URB2 | c.4471del p.A1491Pfs*7 | Frame Shift Del (DEL) | VAF 163/432 reads (38%) | catalogued as COSV99270446; called by mutect2, pindel, varscan2
- VCAM1 | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 105/292 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54121456; called by muse, varscan2
- VPS13A | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 45/496 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs780834260, COSV100652608, COSV100653415; called by muse, mutect2
- WIZ | c.2452C>T p.R818C (on ENST00000673675 / NM_001371589.1; = p.R81C on NM_021241.3) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs763355086, COSV54611713; called by muse, mutect2, varscan2
- XIRP2 | c.5626C>A p.H1876N (on ENST00000628543; = p.H2051N on NM_152381.6) | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV54712601, COSV54732721; called by muse, mutect2, varscan2
- XKR4 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 148/287 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs771227530, COSV59333502; called by muse, mutect2, varscan2
- XKR4 | c.1262C>A p.T421K | Missense Mutation (SNP) | VAF 168/324 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59309095; called by muse, mutect2, varscan2
- ZBP1 | c.438G>C p.R146S | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV100473706; called by muse, mutect2, varscan2
- ZCCHC7 | c.814G>C p.G272R | Missense Mutation (SNP) | VAF 190/295 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757250294; called by muse, mutect2, varscan2
- ZCWPW1 | c.1885G>T p.G629W | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.965); catalogued as COSV52202266, COSV99546675; called by muse, mutect2
- ZFR2 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs1298114729; called by muse, mutect2, varscan2
- ZMAT3 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 45/161 reads (28%) | catalogued as rs763416591, COSV100265321; called by muse, mutect2, varscan2
- ZNF536 | c.500C>A p.A167E | Missense Mutation (SNP) | VAF 134/273 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100835381, COSV62827327; called by muse, mutect2, varscan2
- ZNF536 | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1392485761, COSV62820033; called by muse, mutect2, varscan2
- ZNF558 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs747562397; called by muse, mutect2, varscan2
- ZNF695 | c.1223A>G p.Y408C | Missense Mutation (SNP) | VAF 109/260 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1331087319; called by muse, mutect2, varscan2
- ZNF695 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.945); catalogued as rs771036143; called by muse, mutect2, varscan2
- ZNF780B | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.107); catalogued as COSV99665182; called by muse, mutect2, varscan2
- ZNF99 | c.2326C>A p.L776I | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68055452; called by muse, mutect2, varscan2
- ABCB1 | c.3579G>T p.Q1193H | Missense Mutation (SNP) | VAF 122/520 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCD2 | c.203G>A p.C68Y | Missense Mutation (SNP) | VAF 78/245 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC004593.2 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AC024940.1 | n.3727A>T | Splice Region (SNP) | VAF 41/133 reads (31%) | called by muse, mutect2, varscan2
- ACKR1 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 91/228 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ACO2 | c.413A>T p.K138I | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); called by muse, varscan2
- ACOT12 | c.431G>T p.R144M | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ACSM2A | c.304G>T p.G102C (on ENST00000219054; = p.G23C on NM_001308169.2) | Missense Mutation (SNP) | VAF 54/396 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ACVRL1 | c.237del p.R80Afs*42 | Frame Shift Del (DEL) | VAF 189/609 reads (31%) | called by mutect2, pindel, varscan2
- ADAM21 | c.1291G>C p.D431H | Missense Mutation (SNP) | VAF 108/465 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ADAM23 | c.2164G>C p.D722H | Missense Mutation (SNP) | VAF 51/300 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ADAM29 | c.869C>A p.T290K | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- ADAMTS12 | c.3095T>A p.L1032Q | Missense Mutation (SNP) | VAF 229/392 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ADAMTS12 | c.1903C>A p.L635I | Missense Mutation (SNP) | VAF 184/345 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ADCY6 | c.3293G>T p.G1098V | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRL3 | c.661C>A p.H221N (on ENST00000506720 / NM_001322402.2; = p.H153N on NM_015236.6) | Missense Mutation (SNP) | VAF 117/265 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ADGRL3 | c.3638del p.G1213Afs*51 (on ENST00000506720 / NM_001322402.2; = p.G1145Afs*51 on NM_015236.6) | Frame Shift Del (DEL) | VAF 174/501 reads (35%) | called by mutect2, pindel, varscan2
- ADRA2A | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 76/138 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- AHI1 | c.1095G>T p.M365I | Missense Mutation (SNP) | VAF 106/229 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- AHSG | c.802G>T p.V268F | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.289); called by muse, varscan2
- AKAP9 | c.6765G>A p.M2255I (on ENST00000359028; = p.M2231I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ALDH1A1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 128/191 reads (67%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH1B1 | c.869G>C p.S290T | Missense Mutation (SNP) | VAF 176/264 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ALDH2 | c.1451G>C p.G484A | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALK | c.1745G>T p.W582L | Missense Mutation (SNP) | VAF 146/427 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ALPK2 | c.5392C>A p.P1798T | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKDD1B | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ANKMY1 | c.1477C>T p.H493Y | Missense Mutation (SNP) | VAF 171/403 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD36B | c.866-1G>T p.X289_splice | Splice Site (SNP) | VAF 24/109 reads (22%) | called by muse, mutect2, varscan2
- AP3S1 | c.521C>A p.P174Q | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.568); called by muse, mutect2
- ARC | c.570G>T p.E190D | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP12 | c.2293G>T p.V765F | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ARHGAP42 | c.1856G>T p.S619I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); called by muse, varscan2
- ARHGEF12 | c.1865A>T p.Q622L | Missense Mutation (SNP) | VAF 95/363 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ARHGEF7 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 110/201 reads (55%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMC10 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARSF | c.1679C>A p.T560K | Missense Mutation (SNP) | VAF 82/154 reads (53%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASCC3 | c.3087G>T p.E1029D | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.95); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ASCC3 | c.1127+1G>C p.X376_splice | Splice Site (SNP) | VAF 58/239 reads (24%) | called by muse, mutect2, varscan2
- ASPM | c.7664A>G p.K2555R | Missense Mutation (SNP) | VAF 101/423 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATG4B | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ATIC | c.1516A>G p.I506V | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP11B | c.1967A>T p.Q656L | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- ATP2B3 | c.2361G>T p.Q787H | Missense Mutation (SNP) | VAF 334/409 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ATP6V0A2 | c.2452A>G p.I818V | Missense Mutation (SNP) | VAF 36/438 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2
- ATR | c.690del p.W230Cfs*3 | Frame Shift Del (DEL) | VAF 89/200 reads (45%) | called by mutect2, pindel, varscan2
- B4GALT6 | c.937G>T p.G313* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- B4GALT6 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BASP1 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 129/263 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCL11B | c.57C>A p.T19= | Splice Region (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
- BEST2 | c.725T>A p.I242N | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- BFSP1 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- BICD2 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 266/513 reads (52%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BOD1L1 | c.4267A>T p.K1423* | Nonsense Mutation (SNP) | VAF 113/321 reads (35%) | called by muse, mutect2, varscan2
- C10orf71 | c.2899G>T p.G967W | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- C1orf94 | c.1202C>A p.A401D (on ENST00000488417 / NM_001134734.2; = p.A211D on NM_032884.5) | Missense Mutation (SNP) | VAF 112/441 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- C2orf16 | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- C5orf49 | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.238); called by muse, mutect2
- CACNA1D | c.1789G>T p.G597C (on ENST00000350061 / NM_001128840.3; = p.G617C on NM_000720.4) | Missense Mutation (SNP) | VAF 346/570 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); called by mutect2, varscan2
- CACNA1D | c.5462C>A p.P1821Q (on ENST00000350061 / NM_001128840.3; = p.P1841Q on NM_000720.4) | Missense Mutation (SNP) | VAF 60/702 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.849); called by muse, mutect2
- CACNA1S | c.1040G>T p.R347M | Missense Mutation (SNP) | VAF 99/391 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CAGE1 | c.1541C>A p.T514N (on ENST00000512086; = p.T378N on NM_205864.3) | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CALB2 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CALY | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 21/138 reads (15%) | called by muse, mutect2, varscan2
- CAMKMT | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 121/367 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAP1 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 154/399 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CC2D2B | c.780+7C>A | Splice Region (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- CCDC142 | c.1627A>G p.S543G (on ENST00000393965 / NM_001365575.2; = p.S536G on NM_032779.4) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- CCM2L | c.1024T>A p.Y342N | Missense Mutation (SNP) | VAF 53/276 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CD1E | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CD247 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 305/732 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDAN1 | c.792G>T p.Q264H | Missense Mutation (SNP) | VAF 110/258 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- CDH2 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 94/429 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- CDH23 | c.9203C>A p.A3068E | Missense Mutation (SNP) | VAF 273/427 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CDH6 | c.1229C>A p.P410Q | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK6 | c.229G>C p.V77L | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2
- CENPF | c.5061G>T p.K1687N | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- CENPU | c.559G>T p.G187* | Nonsense Mutation (SNP) | VAF 155/281 reads (55%) | called by muse, mutect2, varscan2
- CEP170B | c.4431C>G p.I1477M (on ENST00000453495; = p.I1406M on NM_015005.3) | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CFAP44 | c.4874A>T p.Q1625L | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CFAP99 | c.708C>A p.N236K | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- CFHR5 | c.584C>G p.S195* | Nonsense Mutation (SNP) | VAF 72/346 reads (21%) | called by muse, mutect2, varscan2
- CFLAR | c.1327C>A p.H443N | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CGB5 | c.466G>T p.G156W | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CHMP4B | c.224A>G p.Y75C | Missense Mutation (SNP) | VAF 35/666 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- CIART | c.519G>T p.M173I | Missense Mutation (SNP) | VAF 141/337 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- CKAP5 | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CLEC17A | c.361+1G>A p.X121_splice | Splice Site (SNP) | VAF 128/359 reads (36%) | called by muse, mutect2, varscan2
- CLIP2 | c.1206G>T p.Q402H | Missense Mutation (SNP) | VAF 118/261 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CMYA5 | c.9960G>T p.Q3320H | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CNTN1 | c.2536G>T p.A846S | Missense Mutation (SNP) | VAF 68/328 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CNTNAP1 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 130/396 reads (33%) | called by muse, mutect2, varscan2
- COL11A1 | c.1351-1G>A p.X451_splice | Splice Site (SNP) | VAF 52/276 reads (19%) | called by muse, mutect2, varscan2
- COL11A2 | c.2042C>A p.P681H (on ENST00000341947 / NM_080680.3; = p.P574H on NM_080679.2) | Missense Mutation (SNP) | VAF 47/441 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL12A1 | c.6766A>T p.S2256C | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- COL3A1 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 95/304 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A1 | c.1526del p.X509_splice | Splice Site (DEL) | VAF 244/570 reads (43%) | called by mutect2, pindel, varscan2
- COX4I2 | c.61A>G p.M21V | Missense Mutation (SNP) | VAF 131/630 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPM | c.175G>T p.V59F | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPNE9 | c.272A>C p.D91A | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- CPS1 | c.3514G>T p.G1172W | Missense Mutation (SNP) | VAF 235/538 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CR1 | c.3116G>C p.G1039A | Missense Mutation (SNP) | VAF 89/614 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRYBG2 | c.3953A>G p.Y1318C | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- CSMD3 | c.1428G>C p.E476D (on ENST00000297405 / NM_001363185.1; = p.E372D on NM_052900.3) | Missense Mutation (SNP) | VAF 198/338 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, varscan2
- CSNK2A1 | c.1138G>T p.G380W | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- CSPG4 | c.1333G>T p.A445S | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, varscan2
- CSRNP1 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CTNNA2 | c.78G>T p.R26S | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- CTNNA3 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.982); called by muse, mutect2
- CUL9 | c.4132C>G p.P1378A | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUX1 | c.1300A>T p.T434S (on ENST00000437600 / NM_181500.4; = p.T436S on NM_001913.5) | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUX2 | c.1657C>A p.L553M | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CX3CL1 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 61/221 reads (28%) | called by muse, mutect2, varscan2
- CYP4X1 | c.1105A>T p.M369L | Missense Mutation (SNP) | VAF 117/236 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- DARS1 | c.923A>T p.D308V | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DCAF12L1 | c.232T>A p.Y78N | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- DCHS1 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 85/399 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- DDI1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 99/332 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX11 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 98/399 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX53 | c.1401C>A p.N467K | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGKK | c.1296G>T p.W432C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DIP2C | c.694del p.T232Qfs*19 | Frame Shift Del (DEL) | VAF 106/346 reads (31%) | called by mutect2, pindel, varscan2
- DLX2 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DLX6 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 98/604 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DMXL2 | c.8765G>T p.G2922V | Missense Mutation (SNP) | VAF 163/392 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DNAH12 | c.2137G>T p.G713W | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DNER | c.1731G>T p.E577D | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DOCK7 | c.5138A>T p.H1713L (on ENST00000635253 / NM_001367561.1; = p.H1682L on NM_033407.3) | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOP1B | c.3608A>T p.Q1203L | Missense Mutation (SNP) | VAF 96/173 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- DPYD | c.2300-1G>T p.X767_splice | Splice Site (SNP) | VAF 177/400 reads (44%) | called by muse, mutect2, varscan2
- DPYS | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 96/551 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DRD3 | c.87T>A p.H29Q | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DSE | c.2458G>T p.D820Y | Missense Mutation (SNP) | VAF 87/183 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- DTNA | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 174/496 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC1H1 | c.10651del p.E3551Nfs*30 | Frame Shift Del (DEL) | VAF 209/763 reads (27%) | called by mutect2, pindel, varscan2
- DYNC1LI2 | c.1044G>T p.L348= | Splice Region (SNP) | VAF 122/473 reads (26%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.2279A>T p.Q760L | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DYTN | c.233C>A p.P78Q | Missense Mutation (SNP) | VAF 193/437 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DZIP1 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 79/146 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- E2F3 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 52/359 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- EDN3 | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 85/427 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- EIF4E3 | c.377G>T p.W126L (on ENST00000425534 / NM_001134651.2; = p.W20L on NM_173359.5) | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- ELP4 | c.224-1G>T p.X75_splice | Splice Site (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- EMILIN2 | c.2107G>T p.E703* | Nonsense Mutation (SNP) | VAF 29/104 reads (28%) | called by muse, mutect2, varscan2
- EPHB1 | c.1694G>C p.R565T | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EPRS1 | c.2396A>G p.Y799C | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ERN2 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 95/168 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ESM1 | c.43C>A p.H15N | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- ETNPPL | c.1185del p.K395Nfs*17 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | called by mutect2, pindel, varscan2
- EVC2 | c.706+1G>C p.X236_splice | Splice Site (SNP) | VAF 97/354 reads (27%) | called by muse, mutect2, varscan2
- EXD1 | c.1028A>T p.E343V | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2
- EXT1 | c.255G>C p.K85N | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYS | c.7132A>C p.N2378H | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- FAM189B | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 68/343 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FAM240C | c.97A>T p.I33F | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, varscan2
- FAM83B | c.1742C>A p.P581Q | Missense Mutation (SNP) | VAF 82/285 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- FAT1 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT2 | c.2402C>T p.S801F | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FBL | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FBN2 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 49/454 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FBN3 | c.2417-1G>T p.X806_splice | Splice Site (SNP) | VAF 37/61 reads (61%) | called by muse, mutect2, varscan2
- FCGBP | c.11703G>T p.Q3901H | Missense Mutation (SNP) | VAF 78/120 reads (65%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FCGBP | c.10891G>T p.A3631S | Missense Mutation (SNP) | VAF 149/263 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FCGR3A | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 207/719 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FCRL3 | c.1736G>T p.G579V | Missense Mutation (SNP) | VAF 169/416 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- FES | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- FLNC | c.7754G>C p.G2585A | Missense Mutation (SNP) | VAF 104/342 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- FNDC10 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- FTCD | c.625G>T p.G209W | Missense Mutation (SNP) | VAF 120/224 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FXR1 | c.1379G>T p.G460V | Missense Mutation (SNP) | VAF 61/303 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FXYD2 | c.156T>A p.C52* | Nonsense Mutation (SNP) | VAF 137/438 reads (31%) | called by muse, mutect2, varscan2
- FYB1 | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 38/390 reads (10%) | called by muse, varscan2
- FYCO1 | c.3646G>T p.G1216C | Missense Mutation (SNP) | VAF 240/612 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- GABBR1 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 42/321 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- GALNT5 | c.1082G>T p.R361M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, varscan2
- GAP43 | c.410C>A p.S137* | Nonsense Mutation (SNP) | VAF 45/161 reads (28%) | called by muse, mutect2, varscan2
- GARRE1 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 106/402 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by mutect2, varscan2
- GASK1A | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- GATA6 | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GBX1 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GFPT2 | c.1120G>T p.G374C | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GFRA1 | c.1390A>T p.T464S | Missense Mutation (SNP) | VAF 201/393 reads (51%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- GIMAP2 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 56/331 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GIMAP4 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 124/308 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- GLP1R | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLRA1 | c.567T>A p.Y189* | Nonsense Mutation (SNP) | VAF 78/361 reads (22%) | called by muse, mutect2, varscan2
- GLT8D2 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GMDS | c.478G>T p.G160W | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNAI1 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2
- GNAL | c.1093G>T p.D365Y (on ENST00000269162 / NM_001142339.3; = p.D442Y on NM_182978.4) | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNPTAB | c.2425G>C p.D809H | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- GPR55 | c.478C>A p.H160N | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- GPR68 | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- GPR88 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT tolerated (0.93); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GRID2IP | c.1430C>A p.P477Q | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- GRM1 | c.247T>A p.F83I | Missense Mutation (SNP) | VAF 216/416 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM3 | c.1738C>A p.P580T | Missense Mutation (SNP) | VAF 115/282 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTPBP4 | c.1454A>T p.K485M | Missense Mutation (SNP) | VAF 64/322 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- GUCD1 | c.631G>T p.G211* | Nonsense Mutation (SNP) | VAF 30/204 reads (15%) | called by muse, mutect2, varscan2
- H3-4 | c.71A>C p.K24T | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); called by muse, mutect2
- HAVCR2 | c.466G>T p.G156* | Nonsense Mutation (SNP) | VAF 32/176 reads (18%) | called by muse, varscan2
- HAVCR2 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, varscan2
- HELB | c.795G>T p.W265C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- HELZ | c.4870A>T p.S1624C | Missense Mutation (SNP) | VAF 102/422 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- HERC2 | c.4427C>A p.S1476* | Nonsense Mutation (SNP) | VAF 18/434 reads (4%) | called by muse, mutect2
- HIVEP3 | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 107/205 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMCN2 | c.1301G>T p.R434M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- HNF4G | c.536A>T p.H179L (on ENST00000354370 / NM_001330561.2; = p.H226L on NM_004133.5) | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- HOOK3 | c.1946A>T p.K649I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.801); called by mutect2, varscan2
- HOXA2 | c.657C>G p.D219E | Missense Mutation (SNP) | VAF 144/517 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HOXD9 | c.887A>T p.Q296L | Missense Mutation (SNP) | VAF 82/300 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HPS5 | c.3058G>T p.G1020C (on ENST00000349215 / NM_181507.2; = p.G906C on NM_007216.4) | Missense Mutation (SNP) | VAF 76/282 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HSD3B1 | c.948C>A p.N316K | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- HSF2 | c.1165C>A p.L389I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- HSPA13 | c.1306G>T p.V436L | Missense Mutation (SNP) | VAF 168/317 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- HYDIN | c.1080G>T p.E360D | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); called by muse, varscan2
- IFIT1B | c.730C>A p.L244M | Missense Mutation (SNP) | VAF 154/261 reads (59%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- IFNA21 | c.238C>A p.L80I | Missense Mutation (SNP) | VAF 91/394 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- IFT81 | c.147A>T p.Q49H | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, varscan2
- IGKV3-20 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGSF21 | c.831G>T p.W277C | Missense Mutation (SNP) | VAF 58/562 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2
- IGSF3 | c.44-1G>T p.X15_splice | Splice Site (SNP) | VAF 26/76 reads (34%) | called by muse, varscan2
- IL1RAP | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- IL2RA | c.571A>T p.S191C | Missense Mutation (SNP) | VAF 85/404 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- INPP5D | c.1989+3G>T | Splice Region (SNP) | VAF 17/189 reads (9%) | called by muse, mutect2
- INSC | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 42/128 reads (33%) | called by muse, mutect2, varscan2
- IRF9 | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 115/258 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- ITGAD | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 90/253 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ITGAL | c.748G>T p.G250W | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ITGAX | c.321C>A p.A107= | Splice Region (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- ITGBL1 | c.153C>A p.C51* | Nonsense Mutation (SNP) | VAF 46/76 reads (61%) | called by muse, varscan2
- ITLN1 | c.686-2A>T p.X229_splice | Splice Site (SNP) | VAF 74/238 reads (31%) | called by muse, mutect2
- KATNIP | c.3164del p.G1055Afs*18 | Frame Shift Del (DEL) | VAF 100/232 reads (43%) | called by mutect2, pindel, varscan2
- KCNA1 | c.1292G>T p.S431I | Missense Mutation (SNP) | VAF 157/244 reads (64%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- KCNH2 | c.1624T>A p.Y542N | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- KCNH5 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 81/349 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNMA1 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 337/545 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- KCNN2 | c.1402G>T p.E468* (on ENST00000264773; = p.E680* on NM_021614.4) | Nonsense Mutation (SNP) | VAF 59/170 reads (35%) | called by muse, mutect2, varscan2
- KCNQ2 | c.2596G>T p.G866C (on ENST00000359125 / NM_172107.4; = p.G838C on NM_004518.6) | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- KCNQ2 | c.2246A>T p.E749V (on ENST00000359125 / NM_172107.4; = p.E721V on NM_004518.6) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- KCNT2 | c.3404T>G p.L1135R | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- KIAA1549 | c.5665A>T p.R1889W (on ENST00000422774 / NM_001164665.2; = p.R1873W on NM_020910.3) | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF27 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KIF2B | c.1448T>C p.L483P | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- KIF2B | c.1871A>T p.Q624L | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIFC2 | c.599A>T p.Q200L | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KMT2B | c.6822G>T p.Q2274H | Missense Mutation (SNP) | VAF 122/209 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KMT2C | c.740-1G>T p.X247_splice | Splice Site (SNP) | VAF 94/226 reads (42%) | called by muse, varscan2
- KRT13 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KRT6B | c.903G>T p.L301F | Missense Mutation (SNP) | VAF 252/848 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- KRT72 | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KRT78 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- KRTAP4-12 | c.553T>A p.C185S | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LAMA1 | c.2435A>T p.D812V | Missense Mutation (SNP) | VAF 107/371 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- LAMA2 | c.1762G>T p.A588S | Missense Mutation (SNP) | VAF 95/297 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.005); called by mutect2, varscan2
- LAMA5 | c.9943-2A>T p.X3315_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- LCOR | c.2959G>T p.V987L | Missense Mutation (SNP) | VAF 182/293 reads (62%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LENG1 | c.39C>A p.N13K | Missense Mutation (SNP) | VAF 75/144 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGALS3BP | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 60/297 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); called by mutect2, varscan2
- LGR5 | c.1442C>A p.A481E | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- LHPP | c.716+1G>T p.X239_splice | Splice Site (SNP) | VAF 49/68 reads (72%) | called by muse, mutect2, varscan2
- LIPC | c.1170-2A>T p.X390_splice | Splice Site (SNP) | VAF 112/275 reads (41%) | called by muse, mutect2, varscan2
- LMNA | c.1669G>T p.D557Y | Missense Mutation (SNP) | VAF 241/857 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- LMOD2 | c.651T>A p.N217K | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LONRF2 | c.1664A>T p.H555L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRFN5 | c.1916T>A p.V639E | Missense Mutation (SNP) | VAF 73/331 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.9221G>A p.C3074Y | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP2 | c.13163A>T p.N4388I | Missense Mutation (SNP) | VAF 48/422 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- LRRC8C | c.1241T>G p.L414R | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRK2 | c.3938G>C p.C1313S | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRTM3 | c.120T>G p.C40W | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LSAMP | c.184_185insC p.V62Afs*15 | Frame Shift Ins (INS) | VAF 148/330 reads (45%) | called by mutect2, varscan2
- LSAMP | c.182dup p.V62Gfs*15 | Frame Shift Ins (INS) | VAF 167/456 reads (37%) | called by mutect2*, pindel, varscan2*
- LTBP1 | c.2213C>A p.S738Y (on ENST00000404816 / NM_206943.4; = p.S412Y on NM_000627.4) | Missense Mutation (SNP) | VAF 86/396 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- MAFA | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- MAGEL2 | c.482A>T p.H161L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated, low confidence (0.11); called by muse, varscan2
- MAML1 | c.818A>G p.E273G | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MAP2 | c.2464G>C p.V822L | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MAP3K20 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAST2 | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- MBD3L2B | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- MCM10 | c.1861C>T p.P621S (on ENST00000484800 / NM_182751.3; = p.P620S on NM_018518.5) | Missense Mutation (SNP) | VAF 91/463 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MDC1 | c.6151A>G p.I2051V | Missense Mutation (SNP) | VAF 79/304 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDN1 | c.6049G>T p.D2017Y | Missense Mutation (SNP) | VAF 98/177 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MEFV | c.1782G>T p.Q594H | Missense Mutation (SNP) | VAF 58/504 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2
- MEIOC | c.1527A>T p.K509N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MEIOC | c.2066C>A p.P689H | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- MEOX2 | c.691G>T p.V231L | Missense Mutation (SNP) | VAF 124/296 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, varscan2
- MGAM | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 79/201 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MGAM2 | c.1296C>A p.S432R | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- MICAL3 | c.2713G>T p.A905S | Missense Mutation (SNP) | VAF 121/491 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MMP14 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 87/347 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- MPHOSPH10 | c.213del p.F71Lfs*52 | Frame Shift Del (DEL) | VAF 75/371 reads (20%) | called by mutect2, pindel, varscan2
- MPPED1 | c.656del p.G219Afs*21 | Frame Shift Del (DEL) | VAF 18/119 reads (15%) | called by mutect2, pindel, varscan2
- MRC1 | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 355/825 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- MRGPRX2 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2
- MROH9 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 92/255 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTMR9 | c.959A>T p.Q320L | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2
- MTOR | c.1430A>T p.Q477L | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.29535C>G p.I9845M | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- MUC17 | c.1862C>T p.T621I | Missense Mutation (SNP) | VAF 101/276 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC22 | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 141/263 reads (54%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- MUC5AC | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT tolerated (0.24); called by muse, mutect2, varscan2
- MUC5B | c.10337C>A p.P3446Q | Missense Mutation (SNP) | VAF 202/804 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.302); called by muse, varscan2
- MXRA5 | c.6409C>A p.L2137M | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MXRA5 | c.4436A>G p.Q1479R | Missense Mutation (SNP) | VAF 96/153 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH4 | c.1178T>G p.L393R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, varscan2
- MYH6 | c.2104G>T p.E702* | Nonsense Mutation (SNP) | VAF 235/712 reads (33%) | called by muse, mutect2, varscan2
- MYO3A | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 85/436 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO3A | c.1568A>G p.E523G | Missense Mutation (SNP) | VAF 110/254 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MYO7A | c.3043C>A p.H1015N | Missense Mutation (SNP) | VAF 162/468 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, varscan2
- MYO7B | c.15G>T p.R5S | Missense Mutation (SNP) | VAF 64/271 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MYO9A | c.3770G>T p.R1257I | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MYOM2 | c.3784G>C p.V1262L | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYOM2 | c.4273G>T p.G1425C | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAALADL2 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 75/242 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NACAD | c.1345C>A p.P449T | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- NBN | c.1738G>C p.V580L | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.422); called by muse, mutect2
- NBPF9 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- NCK2 | c.831C>A p.S277R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NDRG3 | c.194T>A p.L65H (on ENST00000349004 / NM_032013.4; = p.L53H on NM_022477.4) | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NDST1 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 185/862 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- NEB | c.9915G>T p.W3305C | Missense Mutation (SNP) | VAF 81/308 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NELL1 | c.973G>T p.G325C | Missense Mutation (SNP) | VAF 100/440 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NELL1 | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- NLRP1 | c.3331_3333delinsA p.P1111Kfs*15 | Frame Shift Del (DEL) | VAF 42/188 reads (22%) | called by pindel, varscan2*
- NLRP9 | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- NMD3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NMD3 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 35/200 reads (18%) | called by muse, mutect2, varscan2
- NOMO1 | c.3197C>T p.S1066F | Missense Mutation (SNP) | VAF 111/253 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- NPAP1 | c.744del p.C248Wfs*34 | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | called by mutect2, pindel, varscan2
- NPFFR2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 88/154 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRDC | c.985G>T p.G329C | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTRK1 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 128/428 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NUDT12 | c.205G>T p.G69W | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP160 | c.3623-1G>A p.X1208_splice | Splice Site (SNP) | VAF 15/264 reads (6%) | called by muse, mutect2
- NUP210L | c.2828T>A p.M943K | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OBSCN | c.16312G>T p.D5438Y | Missense Mutation (SNP) | VAF 152/603 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OBSL1 | c.3467_3468del p.R1156Pfs*2 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | called by mutect2, pindel*
- OCM | c.17T>A p.V6E | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- OCSTAMP | c.253G>C p.A85P | Missense Mutation (SNP) | VAF 135/566 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OGFOD3 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 92/459 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- OR10A5 | c.148_151delinsTT p.T50Ffs*3 | Frame Shift Del (DEL) | VAF 75/558 reads (13%) | called by pindel, varscan2*
- OR13D1 | c.1002_1019del p.K334_H340delinsN | In Frame Del (DEL) | VAF 26/46 reads (57%) | called by mutect2, pindel
- OR14C36 | c.230C>G p.P77R | Missense Mutation (SNP) | VAF 107/244 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR2M4 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 80/293 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- OR2T6 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR4C3 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- OR4C3 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.023); called by muse, varscan2
- OR4K15 | c.483C>A p.S161R (on ENST00000305051; = p.S137R on NM_001005486.1) | Missense Mutation (SNP) | VAF 109/346 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- OR4K17 | c.338T>A p.V113E | Missense Mutation (SNP) | VAF 119/325 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- OR4N5 | c.518A>T p.Q173L | Missense Mutation (SNP) | VAF 47/399 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- OR51C1P | c.696A>C p.E232D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OR51E2 | c.208C>A p.L70M | Missense Mutation (SNP) | VAF 110/291 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- OR52N1 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 38/116 reads (33%) | called by muse, mutect2, varscan2
- OR52N4 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 129/361 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- OR5D16 | c.458G>T p.W153L | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- OR6B1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6C74 | c.318_319dup p.A107Gfs*29 | Frame Shift Ins (INS) | VAF 22/94 reads (23%) | called by mutect2, pindel, varscan2
- OR8B8 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 84/285 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OR8H2 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- OR8K3 | c.322A>T p.I108F | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- OR9A2 | c.832del p.T278Pfs*4 | Frame Shift Del (DEL) | VAF 15/169 reads (9%) | called by mutect2, pindel
- OSBPL2 | c.386G>T p.R129M (on ENST00000313733 / NM_144498.4; = p.R117M on NM_014835.4) | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OSBPL7 | c.2178G>C p.M726I | Missense Mutation (SNP) | VAF 84/210 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- OTOG | c.7198C>G p.L2400V | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- OTP | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PALM3 | c.716A>T p.E239V (on ENST00000340790; = p.E254V on NM_001145028.2) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- PCDH1 | c.2203A>T p.T735S | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCDHB10 | c.1665C>A p.N555K | Missense Mutation (SNP) | VAF 119/698 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCDHB2 | c.1742C>A p.A581E | Missense Mutation (SNP) | VAF 122/626 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PCDHB5 | c.2161G>T p.V721F | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- PCDHB8 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 64/450 reads (14%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHGA2 | c.1526C>A p.S509Y | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHGB2 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCMTD2 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNX1 | c.6769G>C p.E2257Q | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PCSK2 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE1B | c.837-1G>C p.X279_splice | Splice Site (SNP) | VAF 68/236 reads (29%) | called by muse, mutect2, varscan2
- PDS5A | c.1922G>T p.G641V | Missense Mutation (SNP) | VAF 96/290 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- PHIP | c.3498A>T p.E1166D | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, varscan2
- PI16 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 46/358 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PIK3R5 | c.1420C>A p.Q474K | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PKD1 | c.7456G>C p.A2486P | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- PKD1L1 | c.5462G>T p.C1821F | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PKD1L3 | c.1994G>T p.C665F | Missense Mutation (SNP) | VAF 115/317 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1 | c.2141T>G p.V714G | Missense Mutation (SNP) | VAF 44/784 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLCXD3 | c.200C>A p.T67N | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PLEK | c.814C>A p.P272T | Missense Mutation (SNP) | VAF 70/338 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHM2 | c.2651G>T p.S884I | Missense Mutation (SNP) | VAF 92/156 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- PLEKHM2 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- PLK1 | c.704G>T p.W235L | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLXNA4 | c.1641G>T p.E547D | Missense Mutation (SNP) | VAF 97/278 reads (35%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- PLXND1 | c.673dup p.R225Pfs*207 | Frame Shift Ins (INS) | VAF 45/353 reads (13%) | called by mutect2, pindel, varscan2
- POLD3 | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POLE | c.1734G>T p.L578F | Missense Mutation (SNP) | VAF 132/307 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- POLH | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 261/548 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- POLQ | c.5194A>T p.N1732Y | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- POP1 | c.179G>T p.R60I | Missense Mutation (SNP) | VAF 188/890 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, varscan2
- POP7 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 140/775 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- POTEE | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 115/405 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- POTEE | c.953C>A p.A318E | Missense Mutation (SNP) | VAF 110/484 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- POTEF | c.1151A>T p.E384V | Missense Mutation (SNP) | VAF 74/340 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- POTEJ | c.2461G>T p.G821W | Missense Mutation (SNP) | VAF 97/389 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPARG | c.611C>A p.S204Y (on ENST00000287820 / NM_015869.5; = p.S174Y on NM_005037.7) | Missense Mutation (SNP) | VAF 38/384 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PPARGC1B | c.1246G>C p.V416L | Missense Mutation (SNP) | VAF 134/298 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PPFIA4 | c.1495G>T p.G499W (on ENST00000447715; = p.G474W on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- PPP1R15B | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 237/609 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PPP1R18 | c.1402A>T p.S468C | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PPP4R3C | c.2218C>A p.P740T | Missense Mutation (SNP) | VAF 131/211 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRAMEF15 | c.1033A>C p.I345L | Missense Mutation (SNP) | VAF 70/1094 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- PRAMEF19 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 467/738 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKCI | c.248A>T p.Q83L | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- PROM1 | c.2219A>T p.K740M | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PRR23C | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PRTG | c.2896G>T p.V966F | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2
- PRUNE2 | c.6122G>T p.S2041I | Missense Mutation (SNP) | VAF 164/305 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PTPN14 | c.1853A>T p.H618L | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- PTPRB | c.3982T>C p.Y1328H | Missense Mutation (SNP) | VAF 118/601 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRE | c.1594G>T p.E532* | Nonsense Mutation (SNP) | VAF 58/104 reads (56%) | called by muse, varscan2
- PTPRH | c.2908G>T p.E970* | Nonsense Mutation (SNP) | VAF 63/123 reads (51%) | called by muse, mutect2, varscan2
- PTPRN | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- PTPRZ1 | c.3619A>T p.I1207L | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRZ1 | c.6098C>A p.S2033* | Nonsense Mutation (SNP) | VAF 40/189 reads (21%) | called by muse, varscan2
- PUM1 | c.2280_2311del p.P761Lfs*21 | Frame Shift Del (DEL) | VAF 40/318 reads (13%) | called by mutect2, pindel
- PXDN | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PXDNL | c.1356G>C p.W452C | Missense Mutation (SNP) | VAF 73/397 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PZP | c.885C>A p.C295* | Nonsense Mutation (SNP) | VAF 152/291 reads (52%) | called by muse, mutect2, varscan2
- R3HDML | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RADIL | c.1640G>T p.C547F | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- RASAL1 | c.123-2A>T p.X41_splice | Splice Site (SNP) | VAF 58/154 reads (38%) | called by muse, mutect2, varscan2
- RASGEF1C | c.37C>G p.P13A | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- RBBP6 | c.4895C>T p.T1632I | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBM19 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- RBMS3 | c.558A>T p.R186S | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RD3L | c.107G>T p.W36L | Missense Mutation (SNP) | VAF 78/338 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RELN | c.847A>T p.I283F | Missense Mutation (SNP) | VAF 182/552 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RFX3 | c.715A>T p.R239W | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RHBG | c.1169C>G p.A390G | Missense Mutation (SNP) | VAF 31/490 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.809); called by muse, mutect2
- RIMS2 | c.1178G>C p.R393T (on ENST00000666250 / NM_001348490.2; = p.R201T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/372 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIOK1 | c.1660G>T p.V554L | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RNF180 | c.853A>C p.S285R | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- RNFT1 | c.1269G>C p.W423C | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ROR1 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 122/320 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ROS1 | c.4477G>T p.E1493* | Nonsense Mutation (SNP) | VAF 107/236 reads (45%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.1106A>T p.D369V | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RRAGD | c.149-2A>T p.X50_splice | Splice Site (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2
- RSBN1L | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- RSPO4 | c.103T>A p.C35S | Missense Mutation (SNP) | VAF 117/411 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RTL10 | c.412C>A p.R138S | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RYR2 | c.5404G>T p.G1802C | Missense Mutation (SNP) | VAF 178/660 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RYR2 | c.5980G>T p.D1994Y | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- S1PR1 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SALL2 | c.2278G>T p.E760* | Nonsense Mutation (SNP) | VAF 121/413 reads (29%) | called by muse, mutect2, varscan2
- SALL2 | c.2277A>T p.E759D | Missense Mutation (SNP) | VAF 119/411 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SAMD12 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SCAMP2 | c.326C>G p.T109S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCFD1 | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCGB1A1 | c.28del p.V10Sfs*46 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, pindel, varscan2
- SCN7A | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCRN2 | c.832A>G p.M278V | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SDHA | c.400G>T p.G134W | Missense Mutation (SNP) | VAF 108/636 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDK1 | c.2576C>A p.A859E | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.223); called by muse, mutect2
- SEC16B | c.2387G>T p.R796M | Missense Mutation (SNP) | VAF 104/435 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEC23A | c.544G>T p.G182C | Missense Mutation (SNP) | VAF 257/563 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SERPINA11 | c.1227C>G p.S409R | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SETD1B | c.5390G>T p.R1797L | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHH | c.300+1G>T p.X100_splice | Splice Site (SNP) | VAF 122/580 reads (21%) | called by muse, mutect2, varscan2
- SHQ1 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 27/350 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.084); called by muse, mutect2
- SIL1 | c.1315G>T p.D439Y | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- SIPA1L1 | c.393G>T p.M131I | Missense Mutation (SNP) | VAF 129/417 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- SLC17A2 | c.1117T>A p.Y373N | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); called by muse, mutect2
- SLC18A3 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 150/373 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC22A7 | c.892T>A p.L298M (on ENST00000372585 / NM_153320.2; = p.L296M on NM_006672.3) | Missense Mutation (SNP) | VAF 119/478 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SLC27A1 | c.986A>T p.Y329F | Missense Mutation (SNP) | VAF 78/161 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SLC41A3 | c.925A>T p.K309* | Nonsense Mutation (SNP) | VAF 29/231 reads (13%) | called by muse, mutect2, varscan2
- SLC5A12 | c.1492A>G p.T498A | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLC5A4 | c.1228T>A p.Y410N | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SLC6A5 | c.1490A>C p.N497T | Missense Mutation (SNP) | VAF 54/534 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLFN14 | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 104/273 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- SLITRK3 | c.2710T>C p.Y904H | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SMC6 | c.2910A>T p.S970= | Splice Region (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- SNAPC1 | c.1094G>T p.R365M | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SNRNP200 | c.4291A>T p.K1431* | Nonsense Mutation (SNP) | VAF 231/732 reads (32%) | called by muse, mutect2, varscan2
- SNRPA1 | c.242A>T p.E81V | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2
- SORBS2 | c.1440C>A p.Y480* | Nonsense Mutation (SNP) | VAF 200/334 reads (60%) | called by muse, mutect2, varscan2
- SOSTDC1 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SP8 | c.603G>T p.E201D (on ENST00000361443 / NM_198956.4; = p.E219D on NM_182700.6) | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31A1 | c.1240C>A p.Q414K | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- SPATA31A3 | c.3310T>G p.F1104V | Missense Mutation (SNP) | VAF 106/1246 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.284); called by muse, mutect2
- SPATA31A3 | c.1873C>A p.Q625K | Missense Mutation (SNP) | VAF 222/1121 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.211); called by mutect2, varscan2
- SPEF2 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 252/442 reads (57%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SPEG | c.2014A>T p.R672* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- SPIRE2 | c.1028A>T p.H343L | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SRD5A3 | c.365-1G>A p.X122_splice | Splice Site (SNP) | VAF 207/510 reads (41%) | called by muse, mutect2, varscan2
- SRPX2 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 108/310 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SSPOP | n.14597T>A | Splice Region (SNP) | VAF 70/151 reads (46%) | called by muse, mutect2, varscan2
- STAG3 | c.2612G>A p.R871H | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- STARD7 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 121/442 reads (27%) | called by muse, mutect2, varscan2
- STAT5B | c.1261C>A p.L421M | Missense Mutation (SNP) | VAF 174/788 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- STIMATE | c.203G>T p.R68M | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- STT3B | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- STX18 | c.795A>T p.R265S | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- STXBP5L | c.2386T>A p.C796S | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STXBP5L | c.3017T>A p.M1006K | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, varscan2
- SUCO | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); called by muse, mutect2
- SUCO | c.1636T>A p.S546T | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.046); called by muse, mutect2
- SUN5 | c.420C>A p.S140R | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SUSD2 | c.1573G>T p.G525* | Nonsense Mutation (SNP) | VAF 35/223 reads (16%) | called by muse, mutect2, varscan2
- SYCE1 | c.776A>T p.Q259L (on ENST00000343131 / NM_001143764.3; = p.Q223L on NM_130784.3) | Missense Mutation (SNP) | VAF 113/226 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- SYT14 | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 227/519 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- SYVN1 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 155/399 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TAOK2 | c.811A>T p.T271S | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TBATA | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 138/220 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- TBC1D31 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 71/401 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.429); called by muse, mutect2, varscan2
439 further variants in this file (79 protein-altering or splice-affecting, 224 silent, 136 other) are not listed here.
